Somatic mutation profile of tumor specimen TCGA-CJ-6031-01A (aliquot TCGA-CJ-6031-01A-11D-1669-08) from TCGA case TCGA-CJ-6031, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 54.5 years (19,905 days).
Specimen TCGA-CJ-6031-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f38d1096-a449-4c6e-baba-06f65d4349a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-6031-11A (Solid Tissue Normal), aliquot TCGA-CJ-6031-11A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d2a68c7-a213-4310-a0ed-07d1a33568c4

The open-access MAF lists 68 somatic variants for this specimen: 56 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 10, Frame Shift Del 9, Nonsense Mutation 5, Frame Shift Ins 3, Intron 1, Translation Start Site 1, Splice Site 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATG7 | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 28/120 reads (23%) | catalogued as rs934600815, COSV61612037; called by muse, mutect2, varscan2
- C1orf112 | c.2489G>A p.W830* | Nonsense Mutation (SNP) | VAF 29/163 reads (18%) | catalogued as COSV53678112; called by muse, mutect2, varscan2
- CFAP43 | c.1429G>A p.V477M | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs145913363, COSV53376560; called by mutect2, varscan2
- CHD5 | c.1332C>A p.N444K | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV52412755; called by muse, mutect2, varscan2
- CHRNB2 | c.580C>A p.L194M | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.039); catalogued as COSV63808039; called by muse, mutect2, varscan2
- CNR2 | c.16del p.V6* | Frame Shift Del (DEL) | VAF 20/193 reads (10%) | catalogued as COSV65692821; called by mutect2, pindel, varscan2
- CRYGS | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV57192328; called by muse, mutect2, varscan2
- ELFN2 | c.2404G>T p.E802* | Nonsense Mutation (SNP) | VAF 13/110 reads (12%) | catalogued as COSV68744386; called by muse, mutect2, varscan2
- FBXO42 | c.611A>C p.E204A | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.059); catalogued as COSV65045368; called by muse, mutect2, varscan2
- FGFR1 | c.787G>T p.A263S (on ENST00000447712 / NM_023110.3; = p.A261S on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV58332859; called by muse, mutect2, varscan2
- FGFR2 | c.707A>C p.E236A | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV60645275; called by muse, mutect2
- FOCAD | c.2291C>T p.S764L | Missense Mutation (SNP) | VAF 52/286 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.049); catalogued as COSV58097420; called by muse, mutect2, varscan2
- FZD3 | c.743T>C p.V248A | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53535212; called by muse, mutect2, varscan2
- HDAC4 | c.253C>G p.Q85E | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61863744; called by muse, mutect2, varscan2
- HYAL4 | c.1442T>C p.L481S | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV56138319; called by muse, mutect2, varscan2
- HYAL4 | c.1443G>T p.L481F | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); catalogued as rs757986808, COSV56138335; called by muse, mutect2, varscan2
- IBTK | c.97A>G p.I33V | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.506); catalogued as COSV60392401; called by muse, mutect2
- KCNH8 | c.1063G>A p.V355I | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.927); catalogued as rs1434905360, COSV60458155; called by muse, mutect2, varscan2
- LCMT2 | c.1075G>T p.G359C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59790179; called by muse, mutect2, varscan2
- LTBP2 | c.5338G>A p.D1780N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.09); catalogued as COSV56207188; called by muse, mutect2, varscan2
- LY75 | c.4658T>C p.L1553S | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV55104631; called by muse, mutect2, varscan2
- MAGEB3 | c.841G>C p.A281P | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64396970; called by muse, mutect2, varscan2
- MAPK3 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV53772811; called by muse, mutect2, varscan2
- MCM7 | c.1457C>A p.A486D | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57995807; called by muse, mutect2, varscan2
- MLANA | c.121C>A p.L41M | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67366765; called by muse, mutect2, varscan2
- MLH3 | c.2461G>T p.A821S | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.018); catalogued as COSV53154481; called by muse, mutect2, varscan2
- NOX3 | c.1249C>T p.L417F | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV50150933; called by muse, mutect2, varscan2
- NSD1 | c.1236+2T>C p.X412_splice | Splice Site (SNP) | VAF 16/106 reads (15%) | catalogued as COSV61774988; called by muse, mutect2, varscan2
- PCDH18 | c.2300G>A p.G767D | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV61267788; called by muse, mutect2, varscan2
- PCDHB13 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 33/129 reads (26%) | catalogued as COSV53395546, COSV53397242; called by muse, mutect2, varscan2
- PIK3C2G | c.84T>G p.N28K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.124); catalogued as COSV56806105; called by muse, mutect2, varscan2
- PLCB3 | c.1763A>T p.E588V | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54187784; called by muse, mutect2, varscan2
- POLQ | c.3605A>C p.E1202A | Missense Mutation (SNP) | VAF 67/421 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.039); catalogued as COSV51750063; called by muse, mutect2, varscan2
- PPP1R16A | c.335G>A p.C112Y | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52952901; called by muse, mutect2, varscan2
- PRPF38B | c.429G>T p.K143N | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as COSV64223767; called by muse, mutect2, varscan2
- PRPF38B | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 22/128 reads (17%) | catalogued as COSV64223778; called by muse, mutect2, varscan2
- RAB24 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.594); catalogued as rs1298442538, COSV57463184; called by muse, mutect2, varscan2
- RXFP1 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.158); catalogued as COSV57049073; called by muse, mutect2, varscan2
- SIK3 | c.1049T>C p.M350T (on ENST00000445177 / NM_001366686.2; = p.M356T on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV52612959; called by muse, mutect2, varscan2
- STRIP1 | c.505A>T p.M169L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV63929789; called by muse, mutect2, varscan2
- SUPT5H | c.688T>A p.Y230N | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63239191; called by muse, mutect2, varscan2
- TLK1 | c.1022G>A p.R341K | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.989); catalogued as COSV62629935; called by muse, mutect2, varscan2
- VHL | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.919); catalogued as rs17855706, COSV56545993, COSV56554828, COSV56559719; called by muse, mutect2
- ZFAND4 | c.1745T>C p.L582S | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV60858702; called by muse, mutect2, varscan2
- CCDC163 | c.62dup p.N21Kfs*6 | Frame Shift Ins (INS) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- FRMPD4 | c.3313dup p.S1105Kfs*31 | Frame Shift Ins (INS) | VAF 34/161 reads (21%) | called by mutect2, pindel, varscan2
- HTT | c.2214_2220del p.L739Pfs*14 | Frame Shift Del (DEL) | VAF 14/147 reads (10%) | called by mutect2, pindel
- LRRK2 | c.4597del p.I1533Sfs*15 | Frame Shift Del (DEL) | VAF 14/102 reads (14%) | called by mutect2, pindel, varscan2
- MYB | c.1327del p.T443Lfs*18 | Frame Shift Del (DEL) | VAF 11/78 reads (14%) | called by mutect2, pindel, varscan2
- MYLK3 | c.1697del p.Q566Rfs*5 | Frame Shift Del (DEL) | VAF 16/126 reads (13%) | called by mutect2, pindel, varscan2
- NPHP3 | c.1680del p.F560Lfs*14 | Frame Shift Del (DEL) | VAF 14/108 reads (13%) | called by mutect2, pindel, varscan2
- OSBP | c.867del p.K289Nfs*62 | Frame Shift Del (DEL) | VAF 17/119 reads (14%) | called by mutect2, pindel, varscan2
- PSD2 | c.211del p.L71Sfs*11 | Frame Shift Del (DEL) | VAF 14/143 reads (10%) | called by mutect2, pindel, varscan2
- SLC25A13 | c.776dup p.K260Efs*11 | Frame Shift Ins (INS) | VAF 33/268 reads (12%) | called by mutect2, pindel, varscan2
- SMAGP | c.22_24del p.P8del | In Frame Del (DEL) | VAF 12/84 reads (14%) | called by mutect2, pindel, varscan2
- ZNF432 | c.746del p.N249Mfs*24 | Frame Shift Del (DEL) | VAF 30/203 reads (15%) | called by mutect2, pindel*, varscan2*
- CA7 | c.720G>A p.R240= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV58156291, COSV58156502; called by muse, mutect2, varscan2
- ETNPPL | c.1152A>G p.E384= | Silent (SNP) | VAF 72/412 reads (17%) | catalogued as COSV56595520; called by muse, mutect2, varscan2
- GSE1 | c.3186C>T p.H1062= | Silent (SNP) | VAF 40/217 reads (18%) | catalogued as COSV53671412; called by muse, mutect2, varscan2
- IBTK | c.99T>A p.I33= | Silent (SNP) | VAF 31/172 reads (18%) | catalogued as COSV60392388; called by muse, mutect2
- MLANA | c.120A>G p.L40= | Silent (SNP) | VAF 22/144 reads (15%) | catalogued as rs770356244, COSV67366758; called by muse, mutect2, varscan2
- NR5A2 | c.342C>A p.V114= (on ENST00000367362 / NM_205860.3; = p.V68= on NM_003822.5) | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as COSV52648865; called by muse, mutect2, varscan2
- PZP | c.1494G>A p.K498= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV54358652; called by muse, mutect2, varscan2
- RASA2 | c.789A>G p.L263= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV53938937; called by mutect2, varscan2
- TMPRSS3 | c.732C>T p.G244= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV52302115; called by muse, mutect2, varscan2
- ZNF710 | c.1629C>G p.P543= | Silent (SNP) | VAF 21/141 reads (15%) | catalogued as COSV51562699; called by muse, mutect2, varscan2
- MIR513A1 | n.88G>A | RNA (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2, varscan2
- NRP2 | c.2440+9456C>T | Intron (SNP) | VAF 36/181 reads (20%) | catalogued as COSV55926758; called by muse, mutect2, varscan2
